Surgical pathology report (de-identified scan), TCGA case TCGA-29-1701, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1701-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

Surg Path

CLINICAL HISTORY:

Pelvic mass. Omental cake with normal ovaries. ? primary.

TCGA-29-1701

GROSS EXAMINATION:

A. "Omentum (AF1)", unfixed. Received are two portions omental cake one measuring 15.0 x 8.0 x 3.0 cm and the other measuring 21.0 x 15.0 x 2.5 cm. The specimen is almost entirely composed of white-tan nodular tissue within the fibroadipose tissue and with extensive hemorrhage. Representative frozen as AF1 with the remnant submitted in block A1. Representative sections in block A3.

B. "Right tube and ovary". Received is a 29.6 gram, 8.5 x 5.5 x 2.0 cm portion of fibroadipose covered with extensive adhesions and nodules measuring less than 0.3 cm in greatest dimension. A single 2.5 x 1.0 x 1.0 cm ovary is seen, also covered by the small excrescences. A single 8.0 cm long x 0.5 cm in greatest diameter fallopian tube with several hemorrhagic overlying adhesions, is also seen within the fibroadipose. Representative ovary and tube is submitted in block B1 with representative surrounding adnexal tissue submitted in block B2.

C. "Left tube and ovary". Received is a 14.3 gram ovary tube and attached adnexa. The 2.0 x 1.5 x 0.7 cm ovary contains scant amount of hemorrhagic surface adhesions and numerous excrescences measuring 0.2 cm, with the adjacent 4.5 cm long fimbriated fallopian tube containing a 1.8 x 1.8 x 1.2 cm pedunculated hemorrhagic white-tan mass at its fimbriated end. The remaining tissue shows numerous small excrescences on the mesothelial surface. Representative ovary in block C1 with representative fallopian tube including mass in block C2.

D. "Uterus and cervix", unfixed. Received is a 59.2 gram, 9.2 x 5.5 x 3.0 cm uterus containing a hemorrhagic but otherwise unremarkable 2.5 x 2.0 cm exocervix containing a 0.2 cm os. The uterus is most remarkable for extensive fundic serosal involvement with an ill-defined friable hemorrhagic white-tan mass, approximately measuring 5.5 x 3.5 x 2.5 cm. The serosal implants appear superficial and do not grossly invade the underlying myometrium. The remainder of the uterus is remarkable only for a single 0.5 cm in greatest dimension endocervical polyp and posterior 0.5 x 0.3 x 0.1 cm sessile endometrial polyp. The remaining 4.0 x 3.0 cm endometrial cavity is lined by a 0.1 cm thick endometrium overlies an unremarkable 0.6 cm myometrium.

BLOCK SUMMARY:

D1- anterior cervix and endomyometrium.
D2- posterior cervix with endocervical polyp.
D3- posterior endomyometrium with endometrial polyp.
D4- fundic endomyometrium with overlying extensive serosal adhesions.
D5-D6- representative serosal mass.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- adenocarcinoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterectomy, bilateral salpingo-oophorectomy, omentectomy.

[REDACTED]

[page 2 of 2]
PATHOLOGIC STAGE: pT3c, pNx, pMx

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM" (EXCISION):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
FIGO GRADE: 3 OF 3.
TUMOR SIZE: GREATER THAN 2 CM.
SEE COMMENT.

TCGA-29-1701

B. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE WITH METASTATIC SEROUS ADENOCARCINOMA.
LYMPHATIC/VASCULAR INVASION IS PRESENT.
SEE COMMENT.

C. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE WITH METASTATIC SEROUS ADENOCARCINOMA.
LYMPHATIC/VASCULAR INVASION IS PRESENT.
SEE COMMENT.

D. "UTERUS" (HYSTERECTOMY):

UTERUS (59.2 GRAMS):
ENDOMETRIUM: CYSTIC ATROPHY, ENDOMETRIAL POLYP.
MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS.
CERVIX: NO PATHOLOGIC DIAGNOSIS.
SEROA: IMPLANTS OF SEROUS ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

COMMENT:

The omentum is extensively involved with a high grade serous adenocarcinoma which retains focal papillary features. Both ovaries show only superficial serosal implants, with less than 0.5 cm of intraparenchymal involvement. Using [REDACTED] criteria, this would be classified as a peritoneal primary. Lymphatic/vascular invasion is seen in the ovaries and in the uterus.

[REDACTED]

Source: NCI Genomic Data Commons file 7ce390b3-bc93-4923-af48-48973b6c8e4b (TCGA-29-1701.F7568046-B77A-4654-9F94-8978BD3E22C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).